Somatic mutation profile of tumor specimen ALCH-B2LX-TTP1-A (aliquot ALCH-B2LX-TTP1-A-1-0-D-A77P-36) from ALCHEMIST case ALCH-B2LX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.7 years (29,471 days).
Specimen ALCH-B2LX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cc083027-5004-44ee-ae14-fac91ede2f8c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B2LX-NB1-A (Blood Derived Normal), aliquot ALCH-B2LX-NB1-A-1-0-D-A77P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cffee277-8d37-400c-9e59-cdd4b2998525

The open-access MAF lists 88 somatic variants for this specimen: 62 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 52, Silent 14, Intron 6, Nonsense Mutation 4, 3'UTR 3, Splice Site 2, Frame Shift Del 2, RNA 2, 3'Flank 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 52/343 reads (15%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ATE1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 33/479 reads (7%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs765527392; called by muse, mutect2
- CCDC151 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 11/140 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.343); catalogued as rs759215057, COSV52950710; called by muse, mutect2
- CSMD3 | c.7384C>T p.R2462W (on ENST00000297405 / NM_001363185.1; = p.R2358W on NM_052900.3) | Missense Mutation (SNP) | VAF 28/694 reads (4%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as rs199998952, COSV52239525; called by muse, mutect2
- DKKL1 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0); catalogued as rs939293013; called by mutect2, varscan2
- INTS14 | c.55A>G p.I19V | Missense Mutation (SNP) | VAF 73/463 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs189663555; called by muse, mutect2, varscan2
- LACRT | c.97C>A p.Q33K | Missense Mutation (SNP) | VAF 29/163 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.037); catalogued as rs1205233747; called by muse, mutect2, varscan2
- NEBL | c.2032C>T p.R678* | Nonsense Mutation (SNP) | VAF 40/452 reads (9%) | catalogued as rs761519235; called by muse, mutect2
- PDHB | c.341A>G p.N114S | Missense Mutation (SNP) | VAF 18/352 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs751436063; called by muse, mutect2
- PRDM8 | c.1982G>A p.R661Q | Missense Mutation (SNP) | VAF 8/224 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1207292488; called by muse, mutect2
- RHBDF1 | c.237G>C p.Q79H | Missense Mutation (SNP) | VAF 19/59 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs1269709407; called by muse, mutect2
- ROBO1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 19/241 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs377297596; called by muse, mutect2
- SLCO1C1 | c.916G>C p.E306Q | Missense Mutation (SNP) | VAF 24/332 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.216); catalogued as COSV56867694; called by muse, mutect2
- SPPL2B | c.1721C>T p.S574F | Missense Mutation (SNP) | VAF 7/128 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs1277911800; called by muse, mutect2
- TP53BP1 | c.3730C>T p.R1244W | Missense Mutation (SNP) | VAF 15/212 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV99779559; called by muse, mutect2
- UBE2O | c.1519G>A p.G507S | Missense Mutation (SNP) | VAF 17/331 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs373042754, COSV60065595; called by muse, mutect2
- ZNF713 | c.944C>A p.S315Y (on ENST00000633730 / NM_001366796.2; = p.S328Y on NM_182633.3) | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT tolerated (0.63); PolyPhen possibly damaging (0.889); catalogued as COSV70056639; called by muse, mutect2
- ZNF730 | c.766T>G p.Y256D | Missense Mutation (SNP) | VAF 5/99 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV74168469; called by muse, mutect2
- AFM | c.1454T>A p.V485E | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.69); called by muse, varscan2
- BANK1 | c.334G>C p.V112L | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CFHR4 | c.1418T>C p.L473P (on ENST00000367416 / NM_001201551.2; = p.L227P on NM_006684.5) | Missense Mutation (SNP) | VAF 46/722 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); called by muse, mutect2
- CNST | c.1703A>T p.N568I | Missense Mutation (SNP) | VAF 15/386 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- CRYBG1 | c.2932A>T p.S978C | Missense Mutation (SNP) | VAF 42/291 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CUX1 | c.3514C>T p.H1172Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- CWF19L2 | c.540A>G p.I180M | Missense Mutation (SNP) | VAF 10/91 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CYP3A7 | c.1366C>G p.L456V | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT tolerated (0.65); PolyPhen benign (0.015); called by muse, mutect2
- DKKL1 | c.277C>G p.H93D | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- DYRK4 | c.1510C>T p.Q504* | Nonsense Mutation (SNP) | VAF 10/68 reads (15%) | called by muse, mutect2, varscan2
- EXOSC9 | c.1316A>G p.N439S | Missense Mutation (SNP) | VAF 8/186 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.011); called by muse, mutect2
- GATA5 | c.908C>T p.S303F | Missense Mutation (SNP) | VAF 8/141 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.62); called by muse, mutect2
- GTPBP2 | c.511C>G p.L171V | Missense Mutation (SNP) | VAF 12/140 reads (9%) | SIFT tolerated (0.15); PolyPhen benign (0.142); called by muse, mutect2
- HERPUD1 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 18/255 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.317); called by muse, mutect2
- ICAM2 | c.225G>A p.W75* | Nonsense Mutation (SNP) | VAF 14/190 reads (7%) | called by muse, mutect2
- IL23R | c.955+1G>T p.X319_splice | Splice Site (SNP) | VAF 26/324 reads (8%) | called by muse, mutect2
- JHY | c.658G>T p.E220* | Nonsense Mutation (SNP) | VAF 20/138 reads (14%) | called by muse, mutect2, varscan2
- LMF1 | c.1261C>A p.L421M | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); called by muse, varscan2
- MAPKAPK2 | c.215T>A p.L72Q | Missense Mutation (SNP) | VAF 31/522 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- MBTPS2 | c.286A>G p.K96E | Missense Mutation (SNP) | VAF 24/638 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.065); called by muse, mutect2
- MMP9 | c.1751-4G>A | Splice Region (SNP) | VAF 8/134 reads (6%) | called by muse, mutect2
- MTUS2 | c.934C>A p.L312M | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.07); called by muse, mutect2
- MYO16 | c.2730+1G>T p.X910_splice | Splice Site (SNP) | VAF 7/134 reads (5%) | called by muse, mutect2
- NCDN | c.1093G>C p.V365L | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NCKAP1L | c.2014A>T p.I672F | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NLRP2 | c.3146A>T p.H1049L | Missense Mutation (SNP) | VAF 24/466 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.031); called by muse, mutect2
- OR11L1 | c.881A>T p.N294I | Missense Mutation (SNP) | VAF 10/197 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR4P4 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.049); called by muse, mutect2
- OSBP2 | c.2263G>C p.E755Q | Missense Mutation (SNP) | VAF 20/198 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PABPC4L | c.952T>C p.S318P | Missense Mutation (SNP) | VAF 20/326 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.878); called by muse, mutect2
- PI4KA | c.4874C>T p.S1625F | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2
- PLCB1 | c.2011G>T p.D671Y | Missense Mutation (SNP) | VAF 22/258 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.254); called by muse, mutect2
- POGZ | c.1026C>A p.N342K | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- RALGDS | c.358del p.T120Rfs*148 | Frame Shift Del (DEL) | VAF 14/95 reads (15%) | called by mutect2, pindel, varscan2
- RBM10 | c.1444del p.A482Pfs*3 | Frame Shift Del (DEL) | VAF 36/202 reads (18%) | called by mutect2, pindel, varscan2
- RTKN2 | c.697T>G p.Y233D | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SDCCAG8 | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 30/394 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.23); called by muse, mutect2
- SEMA5A | c.38G>A p.S13N | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.395); called by muse, mutect2
- SERPINA11 | c.397C>A p.L133I | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.417); called by muse, mutect2
- SLC35B1 | c.299A>G p.N100S (on ENST00000649906; = p.N63S on NM_005827.4) | Missense Mutation (SNP) | VAF 8/183 reads (4%) | SIFT deleterious (0.05); PolyPhen benign (0.129); called by muse, mutect2
- SLC5A1 | c.603T>G p.I201M | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.983); called by muse, mutect2
- TSC1 | c.54G>A p.M18I | Missense Mutation (SNP) | VAF 41/451 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- ZNF714 | c.97G>C p.E33Q | Missense Mutation (SNP) | VAF 14/208 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2
- ZNF717 | c.2591A>C p.H864P | Missense Mutation (SNP) | VAF 7/175 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ADCYAP1R1 | c.939G>A p.V313= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as rs766962141; called by muse, mutect2
- CDIN1 | c.243T>C p.A81= | Silent (SNP) | VAF 12/254 reads (5%) | called by muse, mutect2
- CLDN14 | c.216G>A p.A72= | Silent (SNP) | VAF 24/292 reads (8%) | catalogued as rs370315827; called by muse, mutect2
- COPS2 | c.1146A>C p.V382= | Silent (SNP) | VAF 13/320 reads (4%) | called by muse, mutect2
- CSMD3 | c.3558C>A p.G1186= (on ENST00000297405 / NM_001363185.1; = p.G1082= on NM_052900.3) | Silent (SNP) | VAF 49/802 reads (6%) | catalogued as rs1333759646, COSV52326145, COSV99851282; called by muse, mutect2
- FAM135B | c.1914T>C p.S638= | Silent (SNP) | VAF 14/207 reads (7%) | called by muse, mutect2
- FLT1 | c.2328A>G p.L776= | Silent (SNP) | VAF 49/361 reads (14%) | called by muse, mutect2, varscan2
- ITPR3 | c.39C>T p.I13= | Silent (SNP) | VAF 9/160 reads (6%) | called by muse, mutect2
- KCNU1 | c.366C>A p.I122= | Silent (SNP) | VAF 12/247 reads (5%) | called by muse, mutect2
- OR2W3 | c.660C>T p.Y220= | Silent (SNP) | VAF 12/228 reads (5%) | called by muse, mutect2
- OSBPL2 | c.1086G>T p.L362= (on ENST00000313733 / NM_144498.4; = p.L350= on NM_014835.4) | Silent (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- PKD1 | c.9885C>T p.N3295= | Silent (SNP) | VAF 23/580 reads (4%) | catalogued as rs764028566, CM074414, COSV99238257; called by muse, mutect2
- TNF | c.444C>G p.T148= | Silent (SNP) | VAF 14/241 reads (6%) | called by muse, mutect2
- VWA8 | c.4338T>C p.P1446= | Silent (SNP) | VAF 18/156 reads (12%) | called by muse, mutect2
- AC005041.1 | chr2:74391875 C>T | 3'Flank (SNP) | VAF 6/129 reads (5%) | called by muse, mutect2
- AC093512.2 | c.*833+28T>G | Intron (SNP) | VAF 16/172 reads (9%) | called by muse, mutect2
- AC138965.1 | n.88-19310A>G | Intron (SNP) | VAF 8/104 reads (8%) | called by muse, mutect2
- CADM3 | c.89-2071C>T | Intron (SNP) | VAF 8/163 reads (5%) | called by muse, mutect2
- CELA2B | c.227+480A>T | Intron (SNP) | VAF 39/297 reads (13%) | called by muse, mutect2, varscan2
- CPLANE1 | c.*2285T>G | 3'UTR (SNP) | VAF 18/262 reads (7%) | called by muse, mutect2
- FGG | c.307+31T>C | Intron (SNP) | VAF 12/155 reads (8%) | called by muse, mutect2
- KITLG | c.*8T>G | 3'UTR (SNP) | VAF 25/416 reads (6%) | called by muse, mutect2
- SARM1 | c.*4514G>A | 3'UTR (SNP) | VAF 15/194 reads (8%) | catalogued as rs781896384; called by muse, mutect2
- SNORD108 | n.17C>A | RNA (SNP) | VAF 8/151 reads (5%) | called by muse, mutect2
- TCF21 | c.451-11C>G | Intron (SNP) | VAF 48/244 reads (20%) | called by muse, varscan2
- UBBP4 | n.611C>T | RNA (SNP) | VAF 37/412 reads (9%) | catalogued as rs1392446520; called by muse, mutect2
